Somatic mutation profile of tumor specimen ASCProject_0089_T1_WES (aliquot ASCProject_0089_T1_WES_1) from CMI case ASCProject_0089, project CMI-ASC: Count Me In (CMI): The Angiosarcoma (ASC) Project. Sex at birth: female; Primary diagnosis: Angiosarcoma; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 34.4 years (12,564 days).
Specimen ASCProject_0089_T1_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Breast; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f4a4497d-20c0-4f4e-a914-8851cd2688fd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ASCProject_0089_SALIVA (Saliva), aliquot ASCProject_0089_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/87c6901b-cac5-42ad-acfb-d6224f0b9175

The open-access MAF lists 26 somatic variants for this specimen: 20 protein-altering or splice-affecting, 6 silent.
By variant classification: Missense Mutation 19, Silent 6, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.3127A>G p.M1043V | Missense Mutation (SNP) | VAF 34/148 reads (23%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.026); catalogued as rs1057519936, COSV55879858, COSV55890961; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ANXA6 | c.634C>T p.R212W | Missense Mutation (SNP) | VAF 21/204 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.939); catalogued as rs1386905312; called by muse, mutect2
- CMTR2 | c.1672G>A p.E558K | Missense Mutation (SNP) | VAF 34/330 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.017); catalogued as rs200731984, COSV57603113; called by muse, mutect2
- GLI3 | c.2770G>A p.A924T | Missense Mutation (SNP) | VAF 36/338 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.696); catalogued as rs1280457707; called by muse, mutect2, varscan2
- HAPLN4 | c.673C>T p.R225W | Missense Mutation (SNP) | VAF 31/110 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.892); catalogued as COSV52270529; called by muse, mutect2, varscan2
- HSD17B11 | c.395C>T p.T132I | Missense Mutation (SNP) | VAF 54/210 reads (26%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.999); catalogued as rs745768164; called by muse, mutect2, varscan2
- MINDY4B | c.1297C>T p.R433* | Nonsense Mutation (SNP) | VAF 67/299 reads (22%) | catalogued as rs566724067, COSV67404295; called by muse, mutect2, varscan2
- PAQR9 | c.721G>A p.A241T | Missense Mutation (SNP) | VAF 43/125 reads (34%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.487); catalogued as COSV61417946; called by muse, mutect2, varscan2
- PLCG1 | c.2248A>G p.M750V | Missense Mutation (SNP) | VAF 76/249 reads (31%) | SIFT tolerated (0.37); PolyPhen benign (0.209); catalogued as COSV54815431; called by muse, mutect2, varscan2
- ADAM22 | c.958A>T p.I320F | Missense Mutation (SNP) | VAF 76/210 reads (36%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ARSK | c.1372G>A p.E458K | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT tolerated (0.34); PolyPhen benign (0.133); called by muse, mutect2
- DNAH17 | c.6617A>G p.D2206G | Missense Mutation (SNP) | VAF 147/312 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); called by muse, mutect2, varscan2
- LRRC7 | c.718G>A p.V240I (on ENST00000651989 / NM_001370785.2; = p.V207I on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 106/360 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.147); called by muse, mutect2, varscan2
- MYO15A | c.2411G>T p.G804V | Missense Mutation (SNP) | VAF 6/91 reads (7%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); called by muse, mutect2
- MYO1F | c.1484G>C p.S495T | Missense Mutation (SNP) | VAF 46/171 reads (27%) | SIFT tolerated (0.21); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- PRKCH | c.823C>A p.Q275K | Missense Mutation (SNP) | VAF 46/165 reads (28%) | SIFT tolerated (0.58); PolyPhen benign (0.174); called by muse, mutect2, varscan2
- PTPRB | c.3313T>A p.W1105R | Missense Mutation (SNP) | VAF 9/237 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- RAB9B | c.404C>T p.T135I | Missense Mutation (SNP) | VAF 64/295 reads (22%) | SIFT tolerated (0.13); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- SLC5A10 | c.686C>T p.A229V | Missense Mutation (SNP) | VAF 33/368 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.155); called by muse, mutect2
- TMEM30A | c.271T>G p.C91G | Missense Mutation (SNP) | VAF 22/217 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); called by muse, mutect2
- ABCC8 | c.2265G>T p.R755= | Silent (SNP) | VAF 96/366 reads (26%) | called by muse, mutect2, varscan2
- CHST13 | c.105A>T p.G35= | Silent (SNP) | VAF 15/146 reads (10%) | called by muse, mutect2, varscan2
- CSRP1 | c.450C>G p.G150= | Silent (SNP) | VAF 70/297 reads (24%) | catalogued as rs1430943551; called by muse, mutect2, varscan2
- DMD | c.5583C>T p.L1861= | Silent (SNP) | VAF 68/333 reads (20%) | catalogued as rs775837149, CD096782; ClinVar: likely benign; called by muse, mutect2, varscan2
- EIF1AX | c.222G>A p.S74= | Silent (SNP) | VAF 18/358 reads (5%) | catalogued as rs1205073984, COSV100792171, COSV100792183; called by muse, mutect2
- ZFP57 | c.153G>T p.V51= | Silent (SNP) | VAF 16/336 reads (5%) | called by muse, mutect2
